Somatic mutation profile of tumor specimen TCGA-BL-A13J-01A (aliquot TCGA-BL-A13J-01A-11D-A10S-08) from TCGA case TCGA-BL-A13J, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.5 years (23,927 days).
Specimen TCGA-BL-A13J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d22a34e-d620-4fa2-a28b-16c4e8b0418d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BL-A13J-10A (Blood Derived Normal), aliquot TCGA-BL-A13J-10A-01D-A271-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/daaf0901-ece9-4844-b679-086a451129ac

The open-access MAF lists 127 somatic variants for this specimen: 92 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 34, Nonsense Mutation 10, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANK1 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | hotspot (GDC flag); catalogued as rs202109621, COSV64160606; called by mutect2, varscan2
- MYH7 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs371898076, CM993620; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 33/51 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 74/424 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs371321397; called by muse, mutect2, varscan2
- ANK2 | c.11525G>A p.R3842Q | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs770954138, COSV100003250, COSV52157432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO4 | c.2554C>A p.P852T (on ENST00000392977 / NM_001286615.2; = p.P817T on NM_178826.4) | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.062); catalogued as COSV54616305; called by muse, mutect2, varscan2
- AP1B1 | c.2204C>G p.S735* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100434874; called by muse, mutect2
- ARHGEF1 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs369443387; called by muse, mutect2, varscan2
- ARHGEF5 | c.2620G>A p.G874S | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs761935499, COSV50221605; called by muse, mutect2, varscan2
- BCAS3 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs766394914, COSV66771518; called by muse, mutect2, varscan2
- CARM1 | c.1775C>A p.S592Y | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); catalogued as COSV53405220; called by muse, mutect2, varscan2
- CDH22 | c.572T>A p.M191K | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV64839925; called by muse, mutect2, varscan2
- CENPE | c.2466C>G p.F822L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV54392225, COSV99477540; called by muse, mutect2, varscan2
- CNTNAP4 | c.2771G>A p.R924K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV56703997; called by muse, mutect2, varscan2
- CPD | c.3145T>A p.C1049S | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.999); catalogued as COSV56716919; called by muse, mutect2, varscan2
- CUBN | c.1618T>C p.S540P | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.856); catalogued as COSV64729121; called by muse, mutect2, varscan2
- DACH1 | c.2150A>T p.D717V (on ENST00000619232 / NM_001366712.1; = p.D463V on NM_004392.6) | Missense Mutation (SNP) | VAF 118/212 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); catalogued as COSV57522063; called by muse, mutect2, varscan2
- DNAJB11 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV54004008, COSV99408766; called by muse, mutect2, varscan2
- DOCK9 | c.3157G>A p.A1053T (on ENST00000376460 / NM_001366676.2; = p.A1054T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59646205; called by muse, mutect2, varscan2
- DYRK4 | c.731C>G p.A244G | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV50546606; called by muse, mutect2, varscan2
- EDC4 | c.858del p.K287Sfs*7 | Frame Shift Del (DEL) | VAF 45/132 reads (34%) | catalogued as COSV62768312; called by mutect2, pindel, varscan2
- EIF2B1 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV99434892; called by muse, mutect2, varscan2
- F8 | c.6383G>C p.G2128A | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64279510; called by muse, mutect2, varscan2
- FAM193A | c.1835C>T p.T612M | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768646940, COSV61199558; called by muse, varscan2
- FASTKD3 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV52947409; called by muse, mutect2, varscan2
- FAT4 | c.6682A>C p.T2228P | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV58712631; called by muse, mutect2, varscan2
- FERD3L | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51764680; called by muse, mutect2, varscan2
- FKBP5 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 104/206 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61884214; called by muse, mutect2, varscan2
- FLG | c.11259G>T p.E3753D | Missense Mutation (SNP) | VAF 172/1272 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.968); catalogued as rs563905924, COSV64242850; called by muse, mutect2, varscan2
- FLRT2 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 102/360 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV58151488; called by muse, mutect2, varscan2
- GTF3C3 | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99827094; called by muse, mutect2, varscan2
- H2BC18 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 53/431 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.338); catalogued as COSV100516198; called by muse, mutect2, varscan2
- HMCN1 | c.12346G>A p.G4116R | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs747104381, COSV54947534; called by muse, mutect2, varscan2
- HOXB4 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as COSV100203873; called by muse, varscan2
- HYI | c.447G>C p.E149D (on ENST00000372434 / NM_001330526.2; = p.E124D on NM_031207.6) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV65095574; called by muse, mutect2, varscan2
- IGLV3-27 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 90/401 reads (22%) | catalogued as rs1356344578; called by muse, mutect2, varscan2
- IMP4 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV52091658, COSV52093015; called by muse, mutect2, varscan2
- ITSN1 | c.4655G>A p.R1552Q | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as rs1408360223, COSV67157162; called by muse, mutect2, varscan2
- KNDC1 | c.2968A>G p.R990G | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.34); catalogued as COSV100466501; called by muse, mutect2, varscan2
- LILRA2 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 106/318 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs555278253, COSV52198103, COSV99253816; called by muse, varscan2
- LRGUK | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 28/189 reads (15%) | catalogued as COSV99604792; called by muse, mutect2, varscan2
- MACF1 | c.19616G>C p.R6539T (on ENST00000372915; = p.R4584T on NM_012090.5) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV57148634; called by muse, mutect2, varscan2
- MAGEE2 | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1405159038, COSV64898666; called by muse, mutect2, varscan2
- MCPH1 | c.2214+1G>A p.X738_splice | Splice Site (SNP) | VAF 15/69 reads (22%) | catalogued as rs772838513, COSV57341032; called by muse, mutect2, varscan2
- MRPL35 | c.376A>C p.K126Q | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV54491979, COSV54494418; called by muse, mutect2, varscan2
- NCF2 | c.1067T>A p.V356E | Missense Mutation (SNP) | VAF 49/459 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62316956; called by muse, mutect2, varscan2
- NUDT14 | c.82-1G>A p.X28_splice | Splice Site (SNP) | VAF 56/229 reads (24%) | catalogued as COSV59650867; called by muse, mutect2, varscan2
- NXPH2 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV55641935, COSV55647471; called by muse, mutect2, varscan2
- NXPH2 | c.526A>T p.T176S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV55647488; called by muse, mutect2, varscan2
- OR10T2 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 32/520 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs772691278, COSV57783296, COSV57784051; called by muse, mutect2
- OR2Z1 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.149); catalogued as rs781891021, COSV60691642; called by muse, mutect2, varscan2
- OR5B21 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.115); catalogued as COSV64482103, COSV64482343; called by muse, mutect2, varscan2
- P3H1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs1440258565, COSV52532704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAK3 | c.1615C>A p.P539T (on ENST00000262836 / NM_001324328.2; = p.P524T on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53281539; called by muse, mutect2, varscan2
- PDE1C | c.1564A>G p.R522G | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV58531640; called by muse, mutect2, varscan2
- PHKA1 | c.2148G>A p.M716I | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV59812647; called by muse, mutect2, varscan2
- PHLPP1 | c.2108del p.L703* | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as COSV99408665; called by mutect2, pindel, varscan2
- PLEKHG5 | c.2689C>T p.R897C (on ENST00000400915 / NM_001042663.3; = p.R860C on NM_020631.6) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.732); catalogued as rs557256913, COSV61070038; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POP1 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs376126108, COSV62894386; called by muse, mutect2, varscan2
- PPFIA1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 316/750 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV54141651; called by muse, mutect2, varscan2
- PPP6R3 | c.923C>A p.A308D | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV55737772; called by muse, mutect2
- RALGPS2 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61340340; called by muse, mutect2, varscan2
- RARA | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV54191093; called by muse, mutect2, varscan2
- RBM10 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61307803; called by muse, mutect2
- RCSD1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); catalogued as rs1221761916, COSV100827816; called by muse, mutect2
- RNASEL | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as COSV62378149; called by muse, mutect2, varscan2
- SCAPER | c.1867G>C p.V623L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV100239823; called by muse, mutect2
- SCN3A | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.176); catalogued as COSV51827121; called by muse, mutect2, varscan2
- SERPINB13 | c.84C>G p.F28L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV54031422, COSV99501058; called by muse, mutect2, varscan2
- SFRP4 | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs765640507, COSV52262265; called by muse, mutect2, varscan2
- SLC38A2 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV56746722; called by muse, varscan2
- SLC7A3 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV53229756, COSV99979486; called by muse, mutect2, varscan2
- SLMAP | c.347-1G>A p.X116_splice | Splice Site (SNP) | VAF 52/73 reads (71%) | catalogued as COSV55854942; called by muse, mutect2, varscan2
- SPAG17 | c.1620G>C p.K540N | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); catalogued as COSV60469139, COSV60470058; called by muse, mutect2, varscan2
- STAG2 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV54372654, COSV54374641; called by muse, varscan2
- TCF4 | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100611100; called by muse, varscan2
- TIAM1 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as COSV54536097, COSV54578339; called by muse, mutect2, varscan2
- TRIM36 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.296); catalogued as COSV56693840; called by muse, mutect2, varscan2
- TRPM5 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV50213534; called by muse, mutect2
- UPB1 | c.618C>A p.N206K | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV58116397; called by muse, mutect2, varscan2
- USP43 | c.2869G>T p.E957* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99557129; called by muse, mutect2, varscan2
- WIF1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs553762024, COSV54134321; called by muse, mutect2
- YAE1 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV56233139, COSV56233976; called by muse, mutect2, varscan2
- ZIM3 | c.649C>G p.H217D | Missense Mutation (SNP) | VAF 41/266 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs150862431, COSV54141873; called by muse, mutect2, varscan2
- ZNF516 | c.1714G>A p.G572S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV71587739; called by muse, mutect2, varscan2
- ZNF626 | c.557C>G p.S186* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | catalogued as rs187292121, COSV74129630; called by muse, mutect2, varscan2
- ZNF644 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV61350774; called by muse, mutect2, varscan2
- ZNF668 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100336980; called by muse, mutect2, varscan2
- ZNF813 | c.883G>T p.G295* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | catalogued as COSV101125020; called by muse, mutect2, varscan2
- ZNF98 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100757660; called by mutect2, varscan2
- SPATA31A1 | c.3526dup p.S1176Ffs*13 | Frame Shift Ins (INS) | VAF 505/643 reads (79%) | called by mutect2, varscan2
- TMX3 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- ADGRV1 | c.6663A>T p.A2221= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV67996752; called by muse, mutect2, varscan2
- AFM | c.1227C>G p.L409= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV56922634; called by muse, mutect2, varscan2
- AHNAK | c.12414G>C p.L4138= | Silent (SNP) | VAF 48/391 reads (12%) | catalogued as rs1487990488, COSV57234149; called by muse, mutect2, varscan2
- ALDOB | c.234C>T p.I78= | Silent (SNP) | VAF 164/264 reads (62%) | catalogued as COSV66398795; called by muse, mutect2, varscan2
- ANO6 | c.2106C>T p.D702= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs201874992, COSV57666426; called by muse, mutect2, varscan2
- ATP8B2 | c.3546G>T p.L1182= (on ENST00000672630; = p.L1149= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as COSV63834297; called by muse, mutect2, varscan2
- C20orf96 | c.999C>G p.V333= (on ENST00000360321 / NM_153269.3; = p.V332= on NM_080571.1) | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as COSV64404769; called by muse, varscan2
- CD300LF | c.807C>T p.L269= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV56899523; called by muse, mutect2, varscan2
- CDH2 | c.369G>A p.L123= | Silent (SNP) | VAF 56/287 reads (20%) | catalogued as COSV52298626; called by muse, mutect2, varscan2
- DLST | c.1350C>G p.L450= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV53168185; called by muse, mutect2, varscan2
- ELOVL7 | c.27G>A p.R9= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs547294540, COSV70918800; called by muse, mutect2, varscan2
- GRM8 | c.945A>T p.I315= | Silent (SNP) | VAF 38/172 reads (22%) | catalogued as COSV58876485; called by muse, mutect2, varscan2
- KCNH1 | c.222G>C p.L74= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs1421785844, COSV55108085; called by muse, mutect2, varscan2
- KCNU1 | c.3063A>T p.P1021= | Silent (SNP) | VAF 73/189 reads (39%) | catalogued as COSV67760357; called by mutect2, varscan2
- KLHL1 | c.1797T>C p.N599= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100918303; called by muse, varscan2
- MAPKAPK3 | c.885C>A p.I295= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV63598716; called by muse, mutect2, varscan2
- MAPKAPK3 | c.1053C>T p.I351= | Silent (SNP) | VAF 43/206 reads (21%) | catalogued as COSV63597883, COSV63598720; called by muse, mutect2, varscan2
- MTTP | c.1791G>C p.L597= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs1315427167, COSV55510522; called by muse, mutect2, varscan2
- NLGN4X | c.1299G>A p.P433= | Silent (SNP) | VAF 42/56 reads (75%) | catalogued as rs761743135, COSV52039892; called by muse, varscan2
- NLRP2 | c.631C>T p.L211= | Silent (SNP) | VAF 64/194 reads (33%) | catalogued as COSV54761380; called by muse, mutect2, varscan2
- OR4C6 | c.897C>T p.L299= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV58606767; called by muse, mutect2, varscan2
- PCDHA1 | c.1356G>A p.A452= | Silent (SNP) | VAF 46/206 reads (22%) | catalogued as rs1324578987, COSV65377384; called by muse, mutect2, varscan2
- POPDC3 | c.249A>G p.V83= | Silent (SNP) | VAF 94/201 reads (47%) | catalogued as rs760385641, COSV54646633; called by muse, mutect2, varscan2
- SEC31A | c.1887C>T p.I629= (on ENST00000355196 / NM_001318120.1; = p.I590= on NM_016211.4) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100022413; called by muse, mutect2
- SLC25A22 | c.855G>A p.L285= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs530958282, COSV57195327; called by muse, mutect2, varscan2
- SLC38A2 | c.249G>C p.A83= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as COSV56746715, COSV99874044; called by muse, mutect2, varscan2
- SVIL | c.4257C>T p.S1419= (on ENST00000355867 / NM_021738.3; = p.S993= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV63449070; called by muse, mutect2, varscan2
- TBXT | c.1131G>T p.R377= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV51619364; called by muse, mutect2, varscan2
- TELO2 | c.1344C>T p.D448= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs370665424; called by muse, mutect2, varscan2
- TGM2 | c.2028G>A p.V676= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100821802; called by muse, mutect2
- TMEM163 | c.384C>T p.D128= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs754153578, COSV56106831; called by muse, mutect2, varscan2
- ZNF285 | c.1311C>T p.F437= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV58411280; called by muse, mutect2, varscan2
- ZNF555 | c.759G>A p.E253= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV62074227; called by muse, mutect2, varscan2
- ZNF831 | c.1881G>T p.T627= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as COSV100926117, COSV64046034; called by muse, varscan2
- BRWD1 | c.6571+146G>A | Intron (SNP) | VAF 72/584 reads (12%) | catalogued as rs749445173, COSV60903824; called by muse, mutect2, varscan2
